Gene-level copy-number profile of tumor specimen HCM-CSHL-0237-C18-01B from HCMI case HCM-CSHL-0237-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.3 years (26,416 days).
Specimen HCM-CSHL-0237-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9cd4b289-f504-4dc6-b56c-8004808c1b44.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0237-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,269 have no estimate.
https://portal.gdc.cancer.gov/files/190e2f0b-a00b-4353-91ff-0c6e5fb4042b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 12; copy number 2: 4,510; copy number 3: 7,009; copy number 4: 36,232; copy number 5: 4,522; copy number 6: 2,856; copy number 7: 1,783; copy number 8: 634; copy number 9: 486; copy number 10: 284; copy number 12: 1; copy number 83: 1; copy number 214: 8; copy number 222: 6.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,940,486–3,955,262, 2 genes: LINC01346, LINC01345.
- chr14:18,418,775–18,588,315, 3 genes (within-gene range 0–5): BNIP3P6, CR383656.13, CR383656.9.
- chr15:25,213,648–25,213,729, 1 gene (within-gene range 0–4): SNORD115-24.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 786 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:143,977,153–144,051,522, 4 genes, copy number 9 (within-gene range 5–9): PARP10, GRINA, SPATC1, SMPD5.
- chr12:911,736–991,190, 2 genes, copy number 214 (within-gene range 4–214): RAD52, AC004803.1.
- chr12:4,247,981–4,405,490, 6 genes, copy number 214: CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23.
- chr12:17,066,368–17,400,914, 6 genes, copy number 222: AC092793.1, RNU6-837P, AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1.
- chr12:17,710,934–17,711,046, 1 gene, copy number 83: Y_RNA.
- chr19:1,228,287–1,244,825, 3 genes, copy number 10 (within-gene range 5–10): CBARP, AC004221.1, ATP5F1D.
- chr20:25,919,499–54,269,542, 627 genes, copy number 9–10 (broad region; genes not listed).
- chr20:61,953,469–64,327,972, 136 genes, copy number 9 (broad region; genes not listed).
- chr21:8,603,547–8,603,984, 1 gene, copy number 12: RPSAP68.

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
